Gene-level copy-number profile of tumor specimen TCGA-XV-AAZY-01A from TCGA case TCGA-XV-AAZY, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 76.5 years (27,938 days).
Specimen TCGA-XV-AAZY-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SKCM.6a081662-c113-4117-93a4-76c2ee0de2da.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-XV-AAZY-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/5d3e72dc-db99-4cfa-8641-081c5b61e013

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 5,688; copy number 2: 53,238; copy number 3: 451; copy number 4: 51; copy number 5: 178; copy number 6: 72; copy number 7: 104; copy number 8: 38.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-XV-AAZY-01A-12D-A400-01): tumor purity 0.46, ploidy 1.91, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 392 genes in 18 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:67,268,022–67,902,600, 12 genes, copy number 5: AC010420.1, AC008459.1, AC112206.2, AC079467.1, AC112206.1, LINC02242, BCL9P1, AC112206.4, AC112206.3, AC106798.1, AC024581.1, AC024581.2.
- chr5:79,372,636–79,686,648, 6 genes, copy number 5: HOMER1, AC093270.1, AC093270.2, Y_RNA, Y_RNA, TENT2.
- chr5:168,486,451–168,667,761, 8 genes, copy number 5: RARS1, FBLL1, PANK3, SLC2A3P1, MIR103A1, MIR103B1, RPL10P9, AC011365.1.
- chr5:173,689,459–174,040,240, 7 genes, copy number 5: LINC01942, LINC01484, AC008674.1, LINC01485, CPEB4, C5orf47, RPL12P22.
- chr5:174,056,060–174,056,585, 1 gene, copy number 5: AC113423.1.
- chr5:179,110,853–179,907,897, 30 genes, copy number 5 (within-gene range 1–5): ADAMTS2, AC109479.3, AC109479.1, AC109479.2, AC136628.1, U4, AC136628.4, AC136628.2, AC136628.3, RUFY1, PRDX2P3, RUFY1-AS1, HNRNPH1, Metazoa_SRP, C5orf60, AC136604.1, AC136604.2, CBY3, CANX, HMGB3P22, MAML1, LTC4S, MGAT4B, MIR1229, SQSTM1, MRNIP, RN7SKP150, Y_RNA, AC008393.1, TBC1D9B.
- chr5:179,933,805–179,940,132, 2 genes, copy number 5: RPS15AP18, AC010285.2.
- chr5:180,100,795–180,209,211, 1 gene, copy number 5 (within-gene range 1–5): RASGEF1C.
- chr17:13,299,184–13,306,771, 1 gene, copy number 6: LINC02093.
- chr17:16,217,191–16,478,678, 14 genes, copy number 6 (within-gene range 1–6): PIGL, MIR1288, CENPV, UBB, AC093484.3, FTLP12, AC093484.2, TRPV2, AC093484.1, SNHG29, SNORD49B, SNORD49A, AC093484.4, SNORD65.
- chr17:20,008,865–20,319,026, 1 gene, copy number 5 (within-gene range 1–5): SPECC1.
- chr17:20,185,082–22,532,522, 110 genes, copy number 5 (broad region; genes not listed).
- chr22:36,560,857–36,703,752, 1 gene, copy number 6 (within-gene range 1–6): CACNG2.
- chr22:36,703,918–36,878,017, 8 genes, copy number 6: AL049749.1, Z80897.2, IFT27, Z80897.1, PVALB, Z82185.1, NCF4-AS1, NCF4.
- chr22:37,180,166–39,155,945, 104 genes, copy number 7 (broad region; genes not listed).
- chr22:40,346,500–41,360,147, 38 genes, copy number 8: ADSL, AL022238.3, SGSM3, SGSM3-AS1, MRTFA, AL022238.2, AL022238.1, MRTFA-AS1, COX6B1P3, RPL4P6, GAPDHP37, MCHR1, SLC25A17, Z98048.1, JTBP1, MIR4766, ST13, XPNPEP3, DNAJB7, Metazoa_SRP, RNU6-379P, RBX1, Y_RNA, AL080243.2, Y_RNA, AL080243.1, MIR1281, EP300, RNU6-375P, AL035658.1, EP300-AS1, LRRC37A14P, L3MBTL2, L3MBTL2-AS1, CHADL, RANGAP1, MIR6889, ZC3H7B.
- chr22:42,364,390–43,187,134, 29 genes, copy number 6: LINC01315, NFAM1, AL022316.1, SERHL, RRP7A, SERHL2, RRP7BP, RN7SKP80, RNU6-513P, POLDIP3, RNU12, Z93241.1, CYB5R3, ATP5MGL, A4GALT, Y_RNA, RPL5P34, GOLGA2P4, AL049757.1, ARFGAP3, PACSIN2, AL049758.1, TTLL1-AS1, TTLL1, AL022237.1, BIK, MCAT, TSPO, TTLL12.
- chr22:43,411,196–44,312,951, 19 genes, copy number 6 (within-gene range 1–6): MPPED1, BX546033.1, EFCAB6-AS1, EFCAB6, Z97055.1, HMGN2P9, Z97055.2, SULT4A1, PNPLA5, PNPLA3, SAMM50, RPL35AP36, PARVB, AL033543.1, AL031595.3, PARVG, AL031595.1, AL031595.2, SHISAL1.

Autosomal genes at a single copy (total copy number 1): 5,688. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
